Somatic mutation profile of tumor specimen C3L-02201-01 (aliquot CPT0127800006) from CPTAC case C3L-02201, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.2 years (24,924 days).
Specimen C3L-02201-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4f2927c-ea1b-4a09-9a91-834c5bc11635.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02201-31 (Blood Derived Normal), aliquot CPT0126610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dc7e044-6e20-4869-a4f3-f4f1d5cea348

The open-access MAF lists 79 somatic variants for this specimen: 54 protein-altering or splice-affecting, 18 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 18, Frame Shift Del 9, Frame Shift Ins 4, Intron 4, In Frame Del 3, Splice Site 3, Nonsense Mutation 3, Splice Region 1, 3'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH16A1 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1461201544; called by muse, mutect2, varscan2
- ANO7 | c.2574+7G>A | Splice Region (SNP) | VAF 20/236 reads (8%) | catalogued as rs775126526; called by muse, mutect2
- CNN1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52957238; called by muse, mutect2, varscan2
- CYP4F8 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs538333797; called by muse, mutect2
- FAM117B | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs757052233; called by muse, mutect2, varscan2
- FKBP4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs1062478; called by muse, mutect2, varscan2
- HEG1 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs911482139; called by muse, mutect2, varscan2
- IGHV1-24 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 135/499 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs139283249; called by muse, mutect2, varscan2
- INPP5D | c.577G>T p.A193S (on ENST00000445964 / NM_001017915.3; = p.A192S on NM_005541.5) | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100856568; called by muse, mutect2, varscan2
- MSR1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV50519383; called by muse, mutect2, varscan2
- MUC16 | c.8801A>C p.E2934A | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV101201182; called by muse, mutect2
- NEB | c.19655A>C p.K6552T | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1559115252; called by muse, mutect2, varscan2
- OR51E1 | c.775G>T p.G259* | Nonsense Mutation (SNP) | VAF 37/150 reads (25%) | catalogued as COSV67809830; called by muse, mutect2, varscan2
- OTUD7A | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs756026648; called by muse, mutect2, varscan2
- RGPD4 | c.4108G>T p.D1370Y | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61749034, COSV61749955; called by muse, varscan2
- RNF213 | c.4237G>T p.A1413S | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1195429371; called by muse, mutect2, varscan2
- SRRM4 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV57422658; called by muse, mutect2, varscan2
- VHL | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 162/357 reads (45%) | catalogued as COSV56553344; called by muse, mutect2, varscan2
- ABCB11 | c.2610+1del p.X870_splice | Splice Site (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.17172_17184del p.T5725Afs*57 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | called by mutect2, pindel, varscan2
- AEBP1 | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 120/422 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- AIP | c.198_199dup p.K67Rfs*90 | Frame Shift Ins (INS) | VAF 101/437 reads (23%) | called by mutect2, pindel, varscan2
- ANO5 | c.88-2A>T p.X30_splice | Splice Site (SNP) | VAF 72/238 reads (30%) | called by muse, varscan2
- ARHGAP5 | c.1395T>A p.Y465* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- BTBD18 | c.992del p.K331Rfs*112 | Frame Shift Del (DEL) | VAF 81/292 reads (28%) | called by mutect2, pindel, varscan2
- CNOT1 | c.5317del p.E1773Kfs*20 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- COPS3 | c.16_18del p.E6del | In Frame Del (DEL) | VAF 31/166 reads (19%) | called by mutect2, pindel, varscan2
- DNAH6 | c.9115_9116del p.I3039* | Frame Shift Del (DEL) | VAF 52/195 reads (27%) | called by mutect2, pindel, varscan2
- DTL | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESR1 | c.589T>A p.Y197N | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXTL3 | c.1186G>T p.V396L | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FBXL16 | c.1292-2A>T p.X431_splice | Splice Site (SNP) | VAF 59/171 reads (35%) | called by muse, mutect2, varscan2
- FRYL | c.6026C>T p.S2009F | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GABRA6 | c.769dup p.L257Pfs*9 | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- GTF2I | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- GTF3C4 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 201/625 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR5A | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- HECTD4 | c.10042G>A p.D3348N | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JAG1 | c.628dup p.Y210Lfs*4 | Frame Shift Ins (INS) | VAF 88/328 reads (27%) | called by mutect2, pindel, varscan2
- KLHDC7B | c.521A>T p.E174V (on ENST00000395676; = p.E815V on NM_138433.5) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NMNAT1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PBRM1 | c.2872_2875del p.Y958Mfs*55 (on ENST00000296302 / NM_001366071.2; = p.Y958Mfs*49 on NM_018313.5) | Frame Shift Del (DEL) | VAF 23/47 reads (49%) | called by mutect2, pindel, varscan2
- PLOD1 | c.1123_1125del p.C375del | In Frame Del (DEL) | VAF 135/441 reads (31%) | called by mutect2, pindel, varscan2
- RALGDS | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 107/344 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SCN7A | c.1736_1739del p.H579Lfs*2 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- SLC27A1 | c.1117_1119del p.E373del | In Frame Del (DEL) | VAF 67/263 reads (25%) | called by pindel, varscan2
- SOGA1 | c.1843A>G p.M615V | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SORCS3 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STARD9 | c.1796dup p.S600Lfs*30 | Frame Shift Ins (INS) | VAF 105/361 reads (29%) | called by mutect2, pindel, varscan2
- THAP2 | c.332del p.L111* | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel
- TYW5 | c.154_158del p.V52Rfs*19 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | called by mutect2, pindel, varscan2
- USP6NL | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- WDR36 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF148 | c.846del p.D282Efs*4 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- ARMC5 | c.192C>T p.R64= | Silent (SNP) | VAF 70/208 reads (34%) | catalogued as rs773106431; called by muse, mutect2, varscan2
- DBNL | c.447C>T p.F149= | Silent (SNP) | VAF 64/209 reads (31%) | catalogued as rs1297923682; called by muse, mutect2, varscan2
- DENND4C | c.4158G>C p.S1386= (on ENST00000434457 / NM_001330640.2; = p.S1337= on NM_017925.7) | Silent (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- ECPAS | c.3321A>G p.G1107= | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- GK2 | c.465T>C p.R155= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs764109930; called by muse, mutect2, varscan2
- HIPK1 | c.1131A>C p.S377= | Silent (SNP) | VAF 34/117 reads (29%) | called by muse, mutect2, varscan2
- IFRD1 | c.141A>C p.S47= | Silent (SNP) | VAF 47/178 reads (26%) | called by muse, mutect2, varscan2
- IL2RB | c.897C>T p.D299= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as rs1291909859, COSV99345178; called by muse, mutect2, varscan2
- KCNG4 | c.531G>A p.K177= | Silent (SNP) | VAF 88/327 reads (27%) | catalogued as rs111998145; called by muse, mutect2, varscan2
- LRRC74B | c.666C>T p.T222= | Silent (SNP) | VAF 40/335 reads (12%) | catalogued as rs553182704; called by muse, mutect2, varscan2
- MBD6 | c.57A>T p.T19= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- NCOR2 | c.3897A>G p.G1299= | Silent (SNP) | VAF 65/174 reads (37%) | called by muse, mutect2, varscan2
- NEK3 | c.759T>C p.S253= | Silent (SNP) | VAF 92/247 reads (37%) | called by muse, mutect2, varscan2
- PLD2 | c.312C>T p.Y104= | Silent (SNP) | VAF 37/137 reads (27%) | called by muse, mutect2, varscan2
- RPUSD2 | c.1560C>G p.A520= | Silent (SNP) | VAF 58/175 reads (33%) | called by muse, mutect2, varscan2
- SON | c.3393T>C p.S1131= | Silent (SNP) | VAF 62/193 reads (32%) | called by muse, mutect2, varscan2
- ZHX2 | c.1035C>T p.I345= | Silent (SNP) | VAF 108/320 reads (34%) | catalogued as rs535426527; called by muse, mutect2, varscan2
- ZNF521 | c.432G>A p.L144= | Silent (SNP) | VAF 69/198 reads (35%) | called by muse, mutect2, varscan2
- KLF6 | c.*19C>G | 3'UTR (SNP) | VAF 147/524 reads (28%) | called by muse, mutect2, varscan2
- LINC02313 | n.214T>G | RNA (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159800 C>T | 5'Flank (SNP) | VAF 98/343 reads (29%) | catalogued as rs561980976; called by muse, mutect2, varscan2
- SCAPER | c.772+1985T>G | Intron (SNP) | VAF 10/22 reads (45%) | catalogued as rs1054099442; called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1016C>A | Intron (SNP) | VAF 53/300 reads (18%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1015T>C | Intron (SNP) | VAF 54/301 reads (18%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.2096+63C>A | Intron (SNP) | VAF 66/236 reads (28%) | catalogued as COSV99649016; called by muse, mutect2, varscan2
